Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5RB, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5RB-01A (Primary Tumor).

Tumor#

Normal #:

1000-3
Astrocytoma NOS 9400/3
Site Path @ Brain NOS C71.9
CGCF Brain, Supratentorial C71.0
JW 2/27/13

Microscopic Description:

Permanent section of the frozen section specimen slide 1A as well as unfrozen 1B demonstrates a mildly to markedly hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. Atypia is generally mild. Tumor cells tend to have a discrete triangular glial cap as well as a modest number of fibrillary processes. Although the nuclei tend to be round to oval, only equivocal perinuclear halos are seen. No mitotic figures are identified. There is no microvascular proliferation or necrosis.

Addendum Microscopic Description:

Sections demonstrate a mild to moderately hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. In addition to the fibrillary astrocytoma pattern seen in specimen 1, there is a minor area that shows classic oligiodendroglioma. Again, mitotic figures are not seen. There is no microvascular proliferation or necrosis. Secondary structures including subpial condensation, perineuronal satellitosis and perivascular accumulation are seen.

The neoplastic cells are diffusely immunoreactive for p53, consistent with astocytic origin. Scattered MIB-1 reactive cells are present. A labeling index of 2.8% is calculated in the most proliferative regions, consistent with the low grade histologic features.

Addendum Diagnosis:

Right frontal brain tumor, biopsy and excision:

Well differentiated astrocytoma (who grade II)

MIB-1 Labeling Index= 2.8%

Source: NCI Genomic Data Commons file a1ccbb3b-61c4-47d5-ac36-65b6f53ad670 (TCGA-HT-A5RB.3DDDF9B9-4EB3-4098-8898-98868D2416D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).